Somatic mutation profile of tumor specimen TCGA-LK-A4O7-01A (aliquot TCGA-LK-A4O7-01A-11D-A34C-32) from TCGA case TCGA-LK-A4O7, project TCGA-MESO (Mesothelioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Epithelioid mesothelioma, malignant; Tissue or organ of origin: Pleura, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 64.6 years (23,606 days).
Specimen TCGA-LK-A4O7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 95759f76-9b66-48ca-b909-2f1ec0f9ba52.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-LK-A4O7-10A (Blood Derived Normal), aliquot TCGA-LK-A4O7-10A-01D-A34C-32; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/21f39cb2-e692-48b2-9a07-e8a8f0ef5c85

The open-access MAF lists 40 somatic variants for this specimen: 31 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 25, Silent 9, Nonsense Mutation 3, Frame Shift Del 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGPAT3 | c.848C>A p.A283E | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT tolerated (0.34); PolyPhen benign (0.014); catalogued as rs763827550; called by muse, mutect2, varscan2
- BAP1 | c.1366C>T p.Q456* | Nonsense Mutation (SNP) | VAF 53/75 reads (71%) | catalogued as COSV56240393, COSV99964331; called by muse, mutect2, varscan2
- DLG5 | c.4792A>G p.I1598V | Missense Mutation (SNP) | VAF 57/147 reads (39%) | SIFT tolerated (0.4); PolyPhen benign (0.015); catalogued as rs766475769; called by muse, mutect2, varscan2
- KANSL3 | c.560G>C p.W187S | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100831211; called by muse, mutect2, varscan2
- MROH8 | c.1826A>G p.N609S | Missense Mutation (SNP) | VAF 37/79 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs754010233; called by muse, mutect2, varscan2
- MYO7B | c.1844A>G p.H615R | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.28); PolyPhen benign (0.024); catalogued as rs778294788; called by muse, mutect2
- NAA15 | c.2330C>T p.P777L | Missense Mutation (SNP) | VAF 65/91 reads (71%) | SIFT tolerated (0.05); PolyPhen benign (0.033); catalogued as rs775375543; called by muse, mutect2, varscan2
- PDCD2 | c.163G>A p.G55S | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated (0.58); PolyPhen benign (0.1); catalogued as rs762795976; called by muse, varscan2
- PDE1C | c.1432G>A p.A478T | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT tolerated (0.58); PolyPhen benign (0.057); catalogued as rs1397681070; called by muse, mutect2, varscan2
- PKP4 | c.1577G>A p.R526H | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.097); catalogued as rs144253065; called by muse, mutect2
- PSD | c.512G>A p.R171Q | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as rs138072390; called by muse, mutect2, varscan2
- THEM5 | c.67C>T p.R23C | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs370864082; called by muse, mutect2, varscan2
- ZNF831 | c.2945C>T p.S982L | Missense Mutation (SNP) | VAF 40/94 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.018); catalogued as rs1277301009, COSV64044656; called by muse, mutect2, varscan2
- BRWD1 | c.6409A>G p.N2137D | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- CAMKV | c.22_36del p.L8_K12del | In Frame Del (DEL) | VAF 42/86 reads (49%) | called by mutect2, pindel, varscan2
- CELA3A | c.707C>T p.T236I | Missense Mutation (SNP) | VAF 33/54 reads (61%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- DIS3L2 | c.713T>C p.I238T | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, varscan2
- KIF6 | c.2306C>G p.T769S | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (0.96); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MAP3K9 | c.1852C>T p.Q618* | Nonsense Mutation (SNP) | VAF 23/43 reads (53%) | called by muse, mutect2, varscan2
- MARS2 | c.44C>T p.A15V | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- NOTCH3 | c.3114G>T p.L1038F | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.536); called by muse, mutect2, varscan2
- PHF20 | c.483T>A p.D161E | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PKP4 | c.393del p.S132Lfs*18 | Frame Shift Del (DEL) | VAF 27/99 reads (27%) | called by mutect2, pindel, varscan2
- RASGRF2 | c.1055A>C p.N352T | Missense Mutation (SNP) | VAF 141/177 reads (80%) | SIFT deleterious (0.04); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- RNF139 | c.65T>G p.L22R | Missense Mutation (SNP) | VAF 70/174 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- RTN3 | c.2114A>C p.D705A (on ENST00000377819 / NM_001265589.2; = p.D686A on NM_201428.3) | Missense Mutation (SNP) | VAF 8/172 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.081); called by muse, mutect2
- SCAMP3 | c.511_515del p.W171Vfs*51 | Frame Shift Del (DEL) | VAF 29/101 reads (29%) | called by mutect2, pindel, varscan2
- SORBS1 | c.172G>C p.D58H | Missense Mutation (SNP) | VAF 35/99 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- SYTL1 | c.950G>A p.R317H (on ENST00000543823; = p.R305H on NM_032872.3) | Missense Mutation (SNP) | VAF 84/144 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- VCAN | c.1402C>T p.H468Y | Missense Mutation (SNP) | VAF 76/207 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- WDR35 | c.1210G>T p.E404* | Nonsense Mutation (SNP) | VAF 31/60 reads (52%) | called by muse, mutect2, varscan2
- ADAMTS20 | c.3687T>G p.T1229= | Silent (SNP) | VAF 27/75 reads (36%) | called by muse, mutect2, varscan2
- AUTS2 | c.222G>T p.R74= | Silent (SNP) | VAF 50/138 reads (36%) | catalogued as COSV100719812; called by muse, mutect2, varscan2
- CNGB1 | c.1512A>C p.P504= | Silent (SNP) | VAF 33/92 reads (36%) | called by muse, mutect2, varscan2
- LBR | c.1702C>T p.L568= | Silent (SNP) | VAF 33/112 reads (29%) | called by muse, mutect2, varscan2
- LILRB2 | c.48C>A p.G16= | Silent (SNP) | VAF 15/42 reads (36%) | called by muse, mutect2, varscan2
- OBSCN | c.2151G>A p.L717= | Silent (SNP) | VAF 14/40 reads (35%) | catalogued as COSV52792460; called by muse, mutect2
- OR56A1 | c.846T>C p.L282= | Silent (SNP) | VAF 29/45 reads (64%) | catalogued as COSV104414036; called by muse, mutect2, varscan2
- TRPM3 | c.3174G>A p.G1058= (on ENST00000357533 / NM_001366142.2; = p.G901= on NM_020952.6) | Silent (SNP) | VAF 55/132 reads (42%) | called by muse, mutect2, varscan2
- TTN | c.101256G>A p.K33752= (on ENST00000591111; = p.K26328= on NM_003319.4) | Silent (SNP) | VAF 44/113 reads (39%) | catalogued as COSV60305503; called by muse, mutect2, varscan2
